Somatic mutation profile of tumor specimen 0DGWOJ from CCDI case PBBTYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.0 years (744 days).
Specimen 0DGWOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e07af0e-bf2a-47ed-bea5-6072cb712b59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGWO7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31f9fb26-faae-49f7-9d20-85ee31ed730c

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 2, 5'UTR 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 251/658 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 1149/1268 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC63 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 567/650 reads (87%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV57527780, COSV57527882; called by muse, varscan2
- MMS19 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs752667384; called by muse, mutect2, varscan2
- NOXO1 | c.1010C>T p.P337L (on ENST00000397280 / NM_172168.3; = p.P331L on NM_144603.4) | Missense Mutation (SNP) | VAF 198/492 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750552005; called by muse, mutect2, varscan2
- PUM1 | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 97/664 reads (15%) | catalogued as rs1205053435, COSV57084513; called by muse, mutect2, varscan2
- PXDN | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 227/845 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as rs1337758716, COSV53242122; called by muse, mutect2, varscan2
- RSF1 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 139/549 reads (25%) | catalogued as COSV57839039; called by muse, mutect2, varscan2
- METTL14 | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 284/734 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MRM2 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 213/522 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- PCM1 | c.4711_4712insTTCCCGTTATTGAAAATC p.N1570_R1571insLPVIEN | In Frame Ins (INS) | VAF 101/687 reads (15%) | called by mutect2, varscan2
- RIPK3 | c.887C>A p.A296D | Missense Mutation (SNP) | VAF 139/349 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TFPI | c.653T>G p.L218R | Missense Mutation (SNP) | VAF 521/970 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- TKTL2 | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 160/436 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CARD8 | c.1206C>T p.F402= (on ENST00000651546 / NM_001184900.3; = p.F352= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 203/547 reads (37%) | called by muse, mutect2, varscan2
- GMDS | c.495A>T p.I165= | Silent (SNP) | VAF 286/701 reads (41%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.-88dup | 5'UTR (INS) | VAF 17/58 reads (29%) | called by mutect2, varscan2
- ME3 | c.*64del | 3'UTR (DEL) | VAF 50/207 reads (24%) | called by mutect2, varscan2
